Somatic mutation profile of tumor specimen TARGET-20-PARIMT-03A (aliquot TARGET-20-PARIMT-03A-01D) from TARGET case TARGET-20-PARIMT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,748 days).
Specimen TARGET-20-PARIMT-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a6a14aa-4c7e-41c7-a73d-76cca50a03ac.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARIMT-14A (Bone Marrow Normal), aliquot TARGET-20-PARIMT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bda9670-2ff6-46b8-b137-facdd603fae1

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 26/180 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2
- FOXP2 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.935); catalogued as COSV63484510; called by muse, mutect2, varscan2
- PTPRJ | c.2241T>A p.N747K | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV69251610; called by muse, mutect2, varscan2
